Somatic mutation profile of tumor specimen 0DJG5I from CCDI case PBBWUN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (796 days).
Specimen 0DJG5I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fdb4fb6-c64c-4156-8b3f-003ad23d80a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJG5G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9441c73b-1ee9-429c-8888-e1f51889d90b

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 6, Nonsense Mutation 1, RNA 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL1 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 71/574 reads (12%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.233); catalogued as rs971577563, COSV59323854; called by muse, mutect2, varscan2
- ACACB | c.6437G>A p.R2146Q | Missense Mutation (SNP) | VAF 375/824 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs374132389, COSV58142184; called by muse, mutect2, varscan2
- IFNL3 | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 56/542 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs775823318, COSV101308030; called by mutect2, varscan2
- METTL14 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 115/1464 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66310637; called by muse, mutect2
- STXBP5L | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 468/1049 reads (45%) | catalogued as rs369496199; called by muse, mutect2, varscan2
- TAGAP | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 177/1166 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs771175774, COSV57853288; called by muse, mutect2, varscan2
- TBKBP1 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 122/839 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1273884824; called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 52/1390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- IRF3 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 337/741 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MARCHF5 | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 47/1027 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2
- TCF23 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 40/1384 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- ZNF274 | c.126G>T p.V42= | Silent (SNP) | VAF 337/779 reads (43%) | called by muse, mutect2, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 16/220 reads (7%) | catalogued as rs1262556378; called by muse, mutect2
- FAM169B | n.352dup | RNA (INS) | VAF 133/1028 reads (13%) | catalogued as rs772573931; called by mutect2, pindel, varscan2
- HNRNPU | c.1670-35T>C | Intron (SNP) | VAF 54/415 reads (13%) | called by muse, mutect2, varscan2
- LGALS4 | c.*8C>T | 3'UTR (SNP) | VAF 357/825 reads (43%) | called by muse, mutect2, varscan2
- PRSS53 | c.1425+69G>A | Intron (SNP) | VAF 115/890 reads (13%) | catalogued as rs1033225973; called by muse, mutect2, varscan2
- SFSWAP | c.388+52G>A | Intron (SNP) | VAF 18/527 reads (3%) | called by muse, mutect2
- SSR4 | c.67+15G>A | Intron (SNP) | VAF 300/687 reads (44%) | called by muse, mutect2, varscan2
- TMEM143 | c.696-36C>A | Intron (SNP) | VAF 64/150 reads (43%) | catalogued as rs765380373; called by muse, mutect2, varscan2
